Somatic mutation profile of tumor specimen MMRF_2621_1_BM_CD138pos (aliquot MMRF_2621_1_BM_CD138pos_T1_KHS5U_L12900) from MMRF case MMRF_2621, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,071 days).
Specimen MMRF_2621_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce5e4a7f-473d-4efd-9bae-a9d7ea247782.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2621_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2621_1_PB_CD3pos_C5_KHS5U_L12899; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da21bc99-9f6c-4cc7-82df-cf6278686a4b

The open-access MAF lists 31 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'UTR 8, Silent 7, Intron 3, 5'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs190358169, COSV99782204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.4489C>A p.L1497I | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422153; called by muse, mutect2
- GADD45B | c.146+7C>T | Splice Region (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99298039; called by muse, mutect2, varscan2
- HSCB | c.382T>G p.Y128D | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750556206; called by muse, mutect2, varscan2
- LPA | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs867934015; called by muse, mutect2
- PROX1 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54783102; called by muse, varscan2
- SLC6A3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431359180; called by mutect2, varscan2
- ZNF205 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs752402312; called by muse, mutect2, varscan2
- PTX3 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SP140 | c.2403G>C p.L801F | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM74 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCB1 | c.1659G>A p.L553= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- ACTG1 | c.234C>T p.N78= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs553335992; called by muse, mutect2, varscan2
- AICDA | c.531G>T p.R177= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- DNAH8 | c.4491T>G p.L1497= | Silent (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2
- MYPOP | c.39C>A p.T13= | Silent (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- PRMT6 | c.1110C>T p.D370= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs1169939697; called by muse, mutect2, varscan2
- SPHK2 | c.963G>A p.V321= | Silent (SNP) | VAF 9/219 reads (4%) | called by muse, mutect2
- ABCB9 | c.1053+88C>A | Intron (SNP) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- BPNT2 | c.*5089G>A | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- CALN1 | c.*6627G>A | 3'UTR (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- CCNL2 | c.*617G>C | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- DAZL | c.*1265G>A | 3'UTR (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- DGKI | c.*138A>T | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- DHDDS | c.542+843A>T | Intron (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- FAM91A1 | c.-222C>T | 5'UTR (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2, varscan2
- KLF6 | c.*2562A>G | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- MIR1197 | n.62C>A | RNA (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- PAX5 | c.*2784C>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SEC63 | c.1675-9C>T | Intron (SNP) | VAF 11/92 reads (12%) | catalogued as rs1190663417; called by mutect2, varscan2
- ZNF592 | c.*523C>T | 3'UTR (SNP) | VAF 25/230 reads (11%) | catalogued as rs1199426606; called by muse, mutect2, varscan2
